Surgical pathology report (de-identified scan), TCGA case TCGA-24-2033, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2033-01A (Primary Tumor).

[page 1 of 8]
DIAGNOSIS

TCGA-24-2033

OVARY, LEFT, SALPINGO-OOPHORECTOMY - ADENOCARCINOMA (SEE COMMENT
AND SYNOPTIC)
- ADENOFIBROMA

OVARY, RIGHT, TOTAL ABDOMINAL HYSTERECTOMY, RIGHT
SALPINGO-OOPHORECTOMY - ADENOCARCINOMA (SEE COMMENT & SYNOPTIC)
- CYSTADENOFIBROMA

UTERUS, TOTAL ABDOMINAL HYSTERECTOMY, RIGHT SALPINGO-OOPHORECTOMY
- ADENOCARCINOMA INVOLVING THE ENDOMETRIUM AND
SEROA, WITH EXTENSIVE MYOMETRIAL INTRAVASCULAR
CARCINOMATOSIS (SEE COMMENT & SYNOPTIC)

CERVIX, TOTAL ABDOMINAL HYSTERECTOMY, RIGHT SALPINGO-OOPHORECTOMY
- METASTATIC ADENOCARCINOMA WITH EXTENSIVE
INTRAVASCULAR CARCINOMATOSIS (SEE COMMENT)

FALLOPIAN TUBE, RIGHT, TOTAL ABDOMINAL HYSTERECTOMY, RIGHT
SALPINGO-OOPHORECTOMY - SEROSAL AND SUBMUCOSAL IMPLANTS OF
METASTATIC ADENOCARCINOMA (SEE COMMENT)

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- SURFACE AND SUBMUCOSAL IMPLANTS OF
METASTATIC ADENOCARCINOMA (SEE COMMENT)

BLADDER, SEROSA, BIOPSY - METASTATIC ADENOCARCINOMA (SEE COMMENT)

OMENTUM, BIOPSY - METASTATIC ADENOCARCINOMA (SEE COMMENT)

SPECIMEN(S) SUBMITTED

Part 1: UTERUS, CERVIX, RSO, LEFT OVARY AND TUBE

Part 2: OMENTUM (PARTIAL)

[page 3 of 8]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Surg. Path. 1.

Name:

HISTORY

The patient is an [REDACTED] with history of increasing abdominal girth and lower extremity edema. Clinical diagnosis: Probably ovarian carcinoma. Operative procedure and findings: Exploratory laparotomy and tumor debulking/total abdominal hysterectomy, bilateral salpingo oophorectomy. An intraoperative non-microscopic consultation was obtained and interpreted as: "Uterus with attached right ovary, fallopian tube, separate left ovary, separate left fallopian tube and fragment of tumor off of bladder. Left ovary is solid and cystic, measuring 11.0 x 5.5 x 4.0 cm and showing tan, friable nodules of tumor internally and on the surface. The right ovary is more solid (8.0 x 4.5 x 2.5 cm) with similar tumor nodules. Separate portion of tan tumor tissue from bladder serosa (6.0 x 3.5 x 1.5 cm); uterus shows 3.0 x 1.5 x 1.0 cm cystic polyp," by [REDACTED]

GROSS

The specimens are received in two containers of formalin, each labelled with the patient's name. The first container is labeled "uterus, cervix, BSO." It contains four separate pieces of tissue. The first piece of tissue is a total abdominal hysterectomy right salpingo oophorectomy that is composed of a 10.0 x 6.0 x 6.0 cm uterus and cervix with an attached 11.0 x 5.05 x 4.0 cm right ovary. The outer surface of the ovary is shaggy tan and brown and covered with multiple 0.1 to 0.2 cm papillary excrescences. The cut surface is composed of variegated white and tan firm tissue with focal 0.1 to 0.4 cm cysts. The lateral most segment of the ovary is replaced by a 4.0 x 2.0 x 2.0 cm hemorrhagic cyst with a wall that ranges from 0.2 to 0.5 cm. The inner lining of the cyst wall smooth and purple with no areas of nodularity. The attached right fallopian tube is 4.0 cm long and 0.7 x 0.7 cm in cross sectional diameter. The fimbriated end of the tube contains a 2.5 x 1.0 x 1.0 cm nodule of firm white and yellow tissue grossly suspicious for metastatic carcinoma. The outer surface of the tube is also studded with multiple small implants. Except for the nodule at the fimbriated end, the lumen of the fallopian tube is unremarkable along its entire course. The anterior wall of the endometrium contains a 3.0 x 1.5 x 1.0 cm

[page 4 of 8]
Name: .

Surg. Path. No.:

GROSS (continued)

polypoid structure with a soft gelatinous cystic cut surface, grossly consistent with an endometrial polyp. The myometrium underlying the endometrial polyp contains a well circumscribed 3.0 x 2.5 x 2.5 cm nodule of firm whorled smooth muscle with no areas of hemorrhage or necrosis, consistent with a leiomyoma. A second small 0.6 x 0.6 x 0.6 cm subserosal leiomyoma is present in the left posterior wall of the uterus at the mid fundus. The myometrium is otherwise unremarkable and ranges in thickness from 1.5 to 2.0 cm. Cut surface is soft, tan with no focal lesions. The lower uterine segment is unremarkable, and, except for the presence of several prominent Nabothian cysts, the ectocervical and endocervical mucosa are also grossly normal. The outer surface of both the uterus and cervix is covered with shaggy firm tan and brown serosal tissue with no grossly evident areas of nodularity. The second piece of tissue received is a separate 11.0 x 5.5 x 4.0 cm left ovary. The outer surface is covered with tan and purple serosa that is focally tan and glistening but is mostly covered by numerous 0.1 to 0.2 cm firm, yellow nodules. The cut surface contains a peripheral 3.5 x 3.0 x 3.0 cm firm yellow and white sclerotic tumor mass, while the remainder of the internal surface is composed of a complex multiloculated thin walled cystic structure with multiple smaller areas of nodularity. A third separate piece of tissue is a 5.5 x 1.0 x 1.0 cm left fallopian tube. The serosal surface is focally covered by shaggy white and yellow 0.1 cm excrescences, suspicious for metastatic carcinoma. Otherwise, the fallopian tube is of normal caliber and shows no areas of dilatation. The luminal cross sectional diameter is uniform at approximately 0.1 cm. The fourth piece of tissue is a 6.0 x 3.5 x 0.9 cm fragment of firm, yellow and white rubbery tissue that was removed from the bladder serosa. its cut surface is uniformly firm and tan with no areas of hemorrhage or necrosis. Blocks submitted: RO1 through RO3 - right ovary; RT1 - fimbriated end of right fallopian tube; RT2 - sections of proximal right fallopian tube; LO1 and LO2 - solid nodule from left ovary; LO4 through LO6 - additional sections of left ovary; LT1 and LT2 - section of left fallopian tube; EM1-EM2 - anterior endometrial wall with polyp; EM3 - anterior lower uterine segment; EM4 - posterior lower uterine segment; EM5 - posterior endometrium; CXA - anterior cervix; CXP - posterior cervix; MM1, MM2 - sections of large leiomyoma; MM3, MM4 - sections of anterior fundus at the

[page 5 of 8]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Surg. Path. No. --

GROSS (continued)

serosal surface showing implants; B1, B2 - bladder serosal tissue.

The second container is labeled "omentum (partial)." It contains a 7.5 x 4.0 x 4.0 cm aggregate of fibrofatty tissue that is diffusely infiltrated by firm white and yellow tissue. Labeled C1 and C2. Jar 2.

COMMENT

There is extensive involvement of both ovaries, both fallopian tubes, the uterus and cervix, bladder serosa, and the omentum by poorly differentiated adenocarcinoma. The most extensive tumor burden is in the ovaries, one or both of which represent primary sites. In the left ovary, the tumor displays two distinctive histologic types (best demonstrated in slides L01 and L02). In some areas, the histologic pattern is distinctly endometrioid with well-formed glands displaying central lumina. The second histologic type, which represents the majority of the tumor, is that of a high grade poorly differentiated adenocarcinoma, most likely representing a papillary serous adenocarcinoma. Both ovaries also contain adenofibromas. It is this poorly differentiated papillary serous component which represents the biologically aggressive component of the neoplasm, as it is the sole histologic subtype in all the metastatic sites. The right ovary shows extensive invasion by poorly differentiated adenocarcinoma. Both fallopian tubes contain serosal implants of metastatic poorly differentiated carcinoma, as well as submucosal invasion of tumor nests. While the majority of the endometrial epithelium is composed of cytologically bland atrophic glands, admixed among the normal elements are islands and nests of metastatic poorly differentiated adenocarcinoma which is indistinguishable from the ovarian tumor. It is not possible to determine with certainty whether the endometrial carcinoma is a second, synchronous primary or metastatic from the ovaries. The entire thickness of the myometrial wall displays numerous intravascular metastases of adenocarcinoma, and numerous uterine serosal implants of tumor are also seen. Extensive submucosal invasive nests and intravascular metastases are also identified in

[page 6 of 8]
Surg. Path. No.:

Name:

COMMENT (continued)

the cervix. The separately submitted bladder and omental biopsies are also completely effaced by high grade metastatic adenocarcinoma.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

- 1a. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is: Mixed endometrioid and papillary serous (see comment)
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent fallopian tube.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
14. Metastatic involvement of the uterine-serosa is PRESENT.
15. Metastatic involvement of the endometrium is PRESENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0.
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME
T3c

FIGO SCHEME
IIIC

DEFINITION
Macroscopic peritoneal
metastasis beyond true pelvis
measuring greater than 2 cm in
greatest dimension

[page 7 of 8]
Name: [REDACTED]

Surg. Path. [REDACTED]

COMMENT (continued)

THE REGIONAL LYMPH NODES are classified as:
NX (Nodal status cannot be assessed) [REDACTED]
THE STATUS OF DISTANT TUMOR SITES is classified as:
MX (Status cannot be assessed) [REDACTED]

20. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME

3c

(T3c/ N0/ M0) OR
(Any T/ N1/ M0)

FIGO SCHEME

IIIC [REDACTED]

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

{End of Report}

[page 8 of 8]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 8264756c-6c60-419a-b6c4-ae13e3440ee1 (TCGA-24-2033.C804DEDF-5495-4051-B87F-974AFE4D5718.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).